Somatic mutation profile of tumor specimen TCGA-B2-4099-01A (aliquot TCGA-B2-4099-01A-02D-1458-08) from TCGA case TCGA-B2-4099, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 83.1 years (30,355 days).
Specimen TCGA-B2-4099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 658f1257-50e3-47d9-9471-27d9a499d67d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-4099-10A (Blood Derived Normal), aliquot TCGA-B2-4099-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf24a7a-edb5-4d4c-a7ee-24532751b20c

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Del 6, Frame Shift Ins 3, Splice Site 2, Nonsense Mutation 2, Intron 1, Nonstop Mutation 1, In Frame Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.4304C>A p.T1435N | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52202216; called by muse, mutect2
- ACSBG2 | c.1096A>C p.N366H | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs766486498, COSV53125179; called by muse, mutect2, varscan2
- ACTG1 | c.367_368del p.M123Vfs*2 | Frame Shift Del (DEL) | VAF 17/186 reads (9%) | catalogued as rs1287600431; called by mutect2, pindel
- ADAM29 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | catalogued as rs945282633, COSV63663914; called by muse, mutect2, varscan2
- CDC42 | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59662132; called by muse, mutect2, varscan2
- CDH18 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV56924826; called by muse, mutect2, varscan2
- CERS2 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV54983364; called by muse, mutect2, varscan2
- CUL1 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57388865; called by muse, mutect2, varscan2
- DCAF12L1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64421832; called by muse, mutect2, varscan2
- DMD | c.10223+1G>T p.X3408_splice | Splice Site (SNP) | VAF 63/120 reads (53%) | catalogued as CS1510030, CS930792, CS971710, COSV58912681; called by muse, mutect2, varscan2
- DNAH7 | c.8015C>A p.A2672D | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417049, COSV56766364; called by muse, mutect2
- ELMO3 | c.1052G>A p.R351Q (on ENST00000652269; = p.R298Q on NM_024712.5) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs777708052, COSV100681496, COSV62606638; called by muse, mutect2, varscan2
- FNIP1 | c.1557A>C p.L519F | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57196644; called by muse, varscan2
- GLYCTK | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV59793773, COSV99980875; called by muse, mutect2, varscan2
- HEATR6 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV51744021, COSV51745822; called by muse, mutect2, varscan2
- KATNIP | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.281); catalogued as COSV55181334, COSV55192900; called by muse, mutect2, varscan2
- KIAA0895L | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV51783271; called by muse, mutect2, varscan2
- KIF19 | c.1097G>T p.S366I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1181893676, COSV63429552; called by muse, mutect2, varscan2
- KLK14 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50068690; called by muse, mutect2, varscan2
- LRRC7 | c.2263G>C p.V755L (on ENST00000651989 / NM_001370785.2; = p.V722L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV50465286; called by muse, mutect2
- LSMEM2 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV57113882; called by muse, mutect2, varscan2
- MAD2L1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.067); catalogued as COSV56636962; called by muse, mutect2, varscan2
- MICAL2 | c.5616G>T p.M1872I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV56286181; called by muse, mutect2
- MTCL1 | c.4685C>T p.P1562L (on ENST00000306329 / NM_001378206.1; = p.P1243L on NM_015210.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1004090574, COSV60406437; called by muse, mutect2, varscan2
- MYH8 | c.4573C>T p.Q1525* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs775373801, COSV67965739; called by muse, mutect2, varscan2
- MYT1L | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV67721089; called by muse, mutect2, varscan2
- NOSIP | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV59198865; called by muse, mutect2
- NSD1 | c.4189C>G p.P1397A | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV61776753; called by muse, mutect2, varscan2
- OR5H1 | c.921dup p.H308Tfs*3 | Frame Shift Ins (INS) | VAF 34/130 reads (26%) | catalogued as rs750155763; called by mutect2, varscan2
- PTPN13 | c.5645C>T p.P1882L (on ENST00000411767 / NM_080683.3; = p.P1863L on NM_006264.3) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1272140271, COSV100363915, COSV57408326; called by muse, mutect2, varscan2
- PYCR1 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV57999349; called by muse, mutect2
- RAB11FIP2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV62925277; called by muse, mutect2, varscan2
- REM1 | c.102C>G p.S34R | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52428347, COSV99147495; called by muse, mutect2, varscan2
- RUFY3 | c.895-1G>T p.X299_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV56913877; called by muse, varscan2
- SLC16A9 | c.758T>A p.L253H | Missense Mutation (SNP) | VAF 178/555 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV68098987; called by muse, mutect2
- STAB2 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 134/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141685549; called by muse, mutect2, varscan2
- SYNJ2BP | c.327T>A p.H109Q | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.198); catalogued as COSV56445755; called by muse, mutect2, varscan2
- TGFBI | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 105/421 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV59351444; called by muse, mutect2, varscan2
- TMEM184C | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56853724; called by muse, mutect2, varscan2
- ZBTB18 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62397052; called by muse, mutect2, varscan2
- ZNF875 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60991515; called by muse, mutect2, varscan2
- ZUP1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63944401; called by muse, mutect2, varscan2
- CNST | c.1054del p.S352Rfs*2 | Frame Shift Del (DEL) | VAF 79/239 reads (33%) | called by mutect2, pindel, varscan2
- HOXA10 | c.1218_1219del p.F407* | Frame Shift Del (DEL) | VAF 59/197 reads (30%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.287A>T p.K96I | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2
- NPM3 | c.240dup p.V81Cfs*10 | Frame Shift Ins (INS) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3278_3299del p.P1093Hfs*59 (on ENST00000296302 / NM_001366071.2; = p.P1068Hfs*59 on NM_018313.5) | Frame Shift Del (DEL) | VAF 79/201 reads (39%) | called by mutect2, pindel, varscan2
- SLK | c.399del p.V134* | Frame Shift Del (DEL) | VAF 50/196 reads (26%) | called by mutect2, pindel, varscan2
- SMYD4 | c.934del p.C312Afs*41 | Frame Shift Del (DEL) | VAF 62/214 reads (29%) | called by mutect2, pindel, varscan2
- TOMM20L | c.107_108insGGT p.D36delinsEV | In Frame Ins (INS) | VAF 12/36 reads (33%) | called by pindel, varscan2
- VHL | c.642_*1del | Nonstop Mutation (DEL) | VAF 14/28 reads (50%) | called by mutect2, pindel
- WDR62 | c.3297_3301delinsTG p.S1100_S1101delinsG | In Frame Del (DEL) | VAF 13/49 reads (27%) | called by pindel, varscan2*
- ZNF564 | c.1183_1184insTT p.C395Ffs*47 | Frame Shift Ins (INS) | VAF 81/373 reads (22%) | called by mutect2, pindel, varscan2
- CLDN3 | c.450G>C p.V150= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV67777164; called by muse, mutect2, varscan2
- H3C11 | c.183G>A p.L61= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV58900156; called by muse, mutect2
- KDM4A | c.606T>C p.F202= | Silent (SNP) | VAF 66/240 reads (28%) | catalogued as rs752886841, COSV64959643; called by muse, mutect2, varscan2
- NHS | c.4233C>T p.F1411= | Silent (SNP) | VAF 60/117 reads (51%) | catalogued as rs774186481, COSV66272605; called by muse, mutect2, varscan2
- OR56A4 | c.255C>T p.P85= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV58110349; called by muse, mutect2
- PCDHB6 | c.2352C>A p.T784= | Silent (SNP) | VAF 52/210 reads (25%) | catalogued as COSV50699397; called by muse, mutect2, varscan2
- PTPN21 | c.255G>A p.K85= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as COSV60848451; called by muse, mutect2, varscan2
- RFPL2 | c.813C>G p.T271= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as COSV50711498; called by muse, mutect2, varscan2
- RYR2 | c.11017C>A p.R3673= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as CM156439, COSV63687431; called by muse, mutect2, varscan2
- SLC35A2 | c.846G>A p.G282= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV54430581; called by muse, mutect2, varscan2
- SLC4A7 | c.1755G>A p.L585= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV55397783; called by muse, mutect2, varscan2
- SYNE2 | c.19470C>G p.P6490= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV59952080; called by muse, mutect2, varscan2
- TMEM69 | c.12C>T p.F4= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV51969537; called by muse, mutect2, varscan2
- ZNF227 | c.1938T>C p.G646= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV57312491; called by muse, mutect2, varscan2
- CANT1 | c.*837del | 3'UTR (DEL) | VAF 4/28 reads (14%) | catalogued as COSV100185292; called by mutect2, pindel
- LHCGR | c.162-1615C>T | Intron (SNP) | VAF 70/224 reads (31%) | catalogued as rs1011562166, COSV54297532; called by muse, mutect2, varscan2
